Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACRK, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACRK-TTP1-A (Primary Tumor).

[page 1 of 2]
Material to be examined and removal site:

1. Lung- left upper lobe
2. Sub aortic lymph node
3. Pleural lymph node
4. Lower apical lymph node
5. Hilar lymph node
6. Interlobar lymph node
7. Lobar lymph node

CDDP-YP-ACRK-01-PR

**Macroscopic report:**

1. pulmonary lobectomy of cm 13x10x3 presents intraparenchymally, nodule grayish of maximum diameter cm 2.2
2. two lymph node of cm 0.7 and 0.9
3. one reddish fragment of cm 0.4
4. three lymph nodes of maximum diameter cm 0.3 - 0.6 and 1
5. one lymph node of cm 1
6. one lymph node of cm 1.5; with nodular reddish area of cm 0.5
7. blackish nodule of cm 0.7

Histopathological diagnosis

1. Adenocarcinoma with areas of muco secreting, moderately differentiated. Bronchial margin and pleura are free. There is a lymphatic metastasis in one of three of the lobar hilum. Four intersegmental lymph nodes are negative.
2. Not metastases observed in the two lymph nodes.
3. Not metastases observed in one lymph nodes.
4. Not metastases observed in the three lymph nodes.
5. Not metastases observed one lymph nodes.
6. Parceled metastases in two lymph nodes
7. Not metastases observed in the two lymph nodes.

ICD-0-3

adenocarcinoma, NOS 8140/3
Site. (L) lung, upper lobe C34.1

Codes SNOMED

T-28000

M-81403

ICD-10

C34.12

Material to be examined and removal site:

Lymph pulmonary vein

hr
12/14/16

Macroscopic report:

Nodule of cm 2.5 that to the cuts looks crumbly, of greyish necrotic color

[page 2 of 2]
Examination extemporaneous

compatible with necrotic metastases

Histopathological diagnosis

Metastasis almost completely necrotic of adenocarcinoma with muco secreting areas

Codes SNOMED

T-C4360

M-81406

W 12/21/16

Source: NCI Genomic Data Commons file 9b2ed024-8c1e-42ce-8f98-b7e91cbf6be9 (CDDP-ACRK-TTP1.66CB3ABC-EE76-4360-BDC8-A36F4B14440F.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).